CCDI case PBCEEN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/74a533ff-fc8f-4719-b475-cd7102a8cbce

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,547 days).

Biospecimens (2 samples)
- Sample 0DPQRR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPQRT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
